Somatic mutation profile of tumor specimen 0DUFEB from CCDI case PBCLAB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.3 years (2,651 days).
Specimen 0DUFEB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4adf1d2e-62ed-448b-b2b3-672dc71f823d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUFDC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2bc9c68-4088-4391-ba61-1b93e6064c9e

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HOXC9 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs1364653355; called by muse, mutect2, varscan2
- ADCY5 | c.1009T>C p.Y337H | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2, varscan2
